Gene-level copy-number profile of tumor specimen TCGA-XP-A8T6-01A from TCGA case TCGA-XP-A8T6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.4 years (19,886 days).
Specimen TCGA-XP-A8T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.d0979e9b-5e35-455d-aa8d-bf8d528808af.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XP-A8T6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/76473519-7f5d-4381-87b2-d8d1863ad76d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,237; copy number 2: 19,269; copy number 3: 22,872; copy number 4: 6,673; copy number 5: 6,040; copy number 6: 1,277; copy number 7: 587; copy number 8: 247; copy number 9: 262; copy number 11: 274; copy number 13: 2; copy number 14: 1; copy number 17: 2; copy number 19: 31; copy number 21: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XP-A8T6-01A-11D-A36I-01): tumor purity 0.47, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,633,065–4,635,654, 1 gene: AC022068.1.
- chr9:21,967,752–22,128,103, 7 genes (within-gene range 0–3): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,381 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:188,905,688–189,133,292, 3 genes, copy number 13–14: LINC01035, CLPTM1LP1, GAPDHP75.
- chr4:51,918,772–51,978,372, 2 genes, copy number 17: AC027271.1, AC104784.1.
- chr5:58,198–11,904,446, 242 genes, copy number 7 (broad region; genes not listed).
- chr8:10,725,399–12,333,693, 71 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 9 (within-gene range 2–9): NSD3.
- chr8:38,335,981–39,580,134, 27 genes, copy number 9: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr8:75,120,409–75,352,327, 1 gene, copy number 9 (within-gene range 4–9): CASC9.
- chr8:75,302,296–75,377,014, 2 genes, copy number 9–11: HIGD1AP6, PKMP4.
- chr8:77,399,072–77,537,290, 1 gene, copy number 9: AC062004.1.
- chr11:68,683,779–76,804,555, 282 genes, copy number 7–9 (broad region; genes not listed).
- chr11:78,435,968–78,582,156, 4 genes, copy number 8 (within-gene range 5–8): NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 8: AP002768.1.
- chr16:46,469,341–49,399,431, 74 genes, copy number 7 (broad region; genes not listed).
- chr16:51,354,456–59,540,266, 216 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr16:68,189,287–69,408,571, 65 genes, copy number 8–21 (within-gene range 2–21) (broad region; genes not listed).
- chr19:15,611,623–16,104,254, 37 genes, copy number 7: AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P, CYP4F2, AC005336.2, AC005336.3, AC005336.1, CYP4F11, OR10H4, CYP4F9P, LINC00661, AC004790.2, LINC00905, SNX33P1, AC004790.1, OR1AB1P, LINC01855, TPM4, AC008894.3, AC008894.1.
- chr19:28,435,388–28,727,680, 1 gene, copy number 7 (within-gene range 4–7): AC005394.2.
- chr19:28,602,379–30,713,538, 43 genes, copy number 7–9: AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr19:31,149,979–38,731,589, 308 genes, copy number 9–19 (within-gene range 3–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 480. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
